CGCI case BLGSP-71-23-00445 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2409eed3-8afb-4737-ac21-89e548474801

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 23 years; Vital status: Dead.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 23.5 years (8,585 days); Year of diagnosis: 2010; Method of diagnosis: Core Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 64 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Bone marrow / Mandible.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -1, day 0, day 64.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Equivocal; Specialized molecular test: Ki-67 > 90%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Lactate Dehydrogenase 2812 [Blood test normal range upper: 480].

Other clinical attributes
- Day -1: Risk factors: HIV/AIDS.
- Day -1: Comorbidities: HIV/AIDS.
- Day 0: Weight: 93.7 kg; Height: 172 cm; BMI: 31.7; Haart treatment indicator: Yes.
- Day 0: Immunosuppressive treatment type: Cyclophosphamide; Risk factor treatment: Yes.
- Day 64: Nadir CD4 count: 53.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00445-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00445-01A-01-S1-HE: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-23-00445-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00445-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lost to follow-up: No.
- History of disease: Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Days from index date to tumor sample procurement: -11.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Mandible.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 2812; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis results: Indeterminate.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: TDT.
